Somatic mutation profile of tumor specimen TCGA-AG-4008-01A (aliquot TCGA-AG-4008-01A-01W-1073-09) from TCGA case TCGA-AG-4008, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 63.5 years (23,192 days).
Specimen TCGA-AG-4008-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e66bc189-e38f-4f5e-b63d-f1f0bd54a6ed.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AG-4008-10A (Blood Derived Normal), aliquot TCGA-AG-4008-10A-01W-1073-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/679bb568-7bee-4482-8b5c-d1eee229a705

The open-access MAF lists 90 somatic variants for this specimen: 70 protein-altering or splice-affecting, 18 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 61, Silent 18, Nonsense Mutation 2, Frame Shift Ins 2, Frame Shift Del 2, In Frame Ins 1, Splice Site 1, 3'Flank 1, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CRB1 | c.1888T>G p.F630V | Missense Mutation (SNP) | VAF 51/329 reads (16%) | hotspot (GDC flag); SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV100957836, COSV100958101, COSV66328724; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 15/68 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 15/68 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.452C>A p.P151H | Missense Mutation (SNP) | VAF 49/94 reads (52%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs1057520000, COSV52677206, COSV52707835, COSV52811105; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ADCY3 | c.2290G>A p.A764T | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs764647486, COSV53164955; called by muse, mutect2, varscan2
- ARID4B | c.3706C>A p.L1236I | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51599190, COSV51611218; called by muse, mutect2, varscan2
- ASCC3 | c.147G>T p.K49N | Missense Mutation (SNP) | VAF 50/291 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.084); catalogued as COSV100225273, COSV61226211; called by muse, mutect2, varscan2
- AVPR1B | c.911C>A p.S304Y | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100899326; called by muse, mutect2, varscan2
- BMP10 | c.370C>T p.R124* | Nonsense Mutation (SNP) | VAF 25/84 reads (30%) | catalogued as rs1156928265, COSV54894260; called by muse, mutect2, varscan2
- BMP4 | c.631C>T p.R211W | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs748940819, COSV55415276; called by muse, mutect2
- BRCA2 | c.5301del p.K1767Nfs*10 | Frame Shift Del (DEL) | VAF 23/175 reads (13%) | catalogued as CD022130; called by mutect2, pindel, varscan2
- C3 | c.1918T>G p.S640A | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV99836215; called by muse, mutect2
- CACNG7 | c.361G>T p.G121C | Missense Mutation (SNP) | VAF 42/83 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55813210, COSV55815433; called by muse, mutect2, varscan2
- CNBD2 | c.1567G>C p.E523Q (on ENST00000373973 / NM_001365709.1; = p.E519Q on NM_080834.4) | Missense Mutation (SNP) | VAF 36/1071 reads (3%) | SIFT tolerated (0.52); PolyPhen benign (0.052); catalogued as COSV100839053; called by muse, mutect2
- DAB1 | c.1639G>C p.E547Q (on ENST00000371231; = p.E514Q on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/216 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.801); catalogued as COSV64690695; called by muse, mutect2, varscan2
- DCDC2 | c.1307C>A p.A436D | Missense Mutation (SNP) | VAF 18/472 reads (4%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as COSV101015276; called by muse, mutect2
- DNAH3 | c.1037C>T p.T346M | Missense Mutation (SNP) | VAF 89/274 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.214); catalogued as rs372982554; called by muse, mutect2, varscan2
- EHBP1 | c.3278C>T p.A1093V | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1253479615, COSV50416454; called by muse, mutect2, varscan2
- FBXW7 | c.1122+2T>C p.X374_splice (on ENST00000281708 / NM_001349798.2; = p.X294_splice on NM_018315.5) | Splice Site (SNP) | VAF 96/304 reads (32%) | catalogued as COSV99655007; called by muse, mutect2, varscan2
- HECTD4 | c.2125A>G p.M709V | Missense Mutation (SNP) | VAF 44/234 reads (19%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.968); catalogued as rs552018424, COSV61178035; called by muse, mutect2, varscan2
- ITIH6 | c.3395C>T p.P1132L | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT deleterious (0.03); PolyPhen benign (0.27); catalogued as rs768389640, COSV54487020; called by muse, mutect2, varscan2
- JAKMIP1 | c.1082C>T p.T361M | Missense Mutation (SNP) | VAF 52/157 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.578); catalogued as rs762649151, COSV51523487; called by muse, mutect2, varscan2
- JAKMIP3 | c.1264G>A p.G422S | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.552); catalogued as rs943352446, COSV53820622; called by muse, mutect2
- KLHL42 | c.1194dup p.C399Vfs*43 | Frame Shift Ins (INS) | VAF 16/136 reads (12%) | catalogued as rs749194179; called by mutect2, varscan2
- KRT37 | c.1066G>A p.G356S | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.098); catalogued as rs761796405, COSV56657069; called by muse, mutect2, varscan2
- LPIN1 | c.2428C>T p.Q810* | Nonsense Mutation (SNP) | VAF 10/190 reads (5%) | catalogued as COSV99877149; called by muse, mutect2
- MAGEB6 | c.602C>T p.T201M | Missense Mutation (SNP) | VAF 89/218 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs768592764, COSV66871774, COSV66872105; called by muse, mutect2, varscan2
- MAP3K19 | c.3889G>A p.A1297T | Missense Mutation (SNP) | VAF 37/126 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770778105, COSV59637036; called by muse, mutect2, varscan2
- MECOM | c.2604G>A p.M868I (on ENST00000468789 / NM_001105078.4; = p.M1056I on NM_004991.4) | Missense Mutation (SNP) | VAF 37/251 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV52960632; called by muse, mutect2, varscan2
- MEPE | c.1442G>A p.R481Q | Missense Mutation (SNP) | VAF 78/244 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0.009); catalogued as rs138152179, COSV100734898; called by muse, mutect2, varscan2
- MMEL1 | c.1327G>A p.V443I | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.336); catalogued as rs751735070, COSV99983398; called by muse, mutect2, varscan2
- MMP16 | c.248A>C p.N83T | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT tolerated (0.65); PolyPhen benign (0.017); catalogued as COSV54174128; called by muse, mutect2
- MRGPRX1 | c.109G>A p.V37I | Missense Mutation (SNP) | VAF 100/264 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs367640618, COSV57105809, COSV57106144; called by muse, mutect2, varscan2
- NCAM2 | c.629C>A p.A210E | Missense Mutation (SNP) | VAF 34/180 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV53059627; called by muse, mutect2, varscan2
- NDST3 | c.1781G>A p.R594H | Missense Mutation (SNP) | VAF 62/195 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs1469620941, COSV56613923; called by muse, mutect2, varscan2
- NLGN4X | c.1021G>A p.G341R | Missense Mutation (SNP) | VAF 73/95 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1220178708, COSV52006855, COSV99319329, COSV99321108; called by muse, mutect2, varscan2
- NPAS4 | c.2014C>A p.L672M | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.854); catalogued as COSV60649103; called by muse, mutect2, varscan2
- OR11H12 | c.245C>T p.S82F | Missense Mutation (SNP) | VAF 59/367 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1211478656, COSV101612489, COSV73569122; called by muse, mutect2, varscan2
- OR4A5 | c.88T>G p.L30V | Missense Mutation (SNP) | VAF 19/169 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.844); catalogued as COSV60521706, COSV60524684; called by muse, mutect2, varscan2
- PAM | c.1582T>A p.F528I | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as COSV57209996; called by muse, mutect2, varscan2
- PCIF1 | c.259T>A p.L87M | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV65026130; called by muse, mutect2
- PEX3 | c.885G>T p.M295I | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT tolerated (0.62); PolyPhen benign (0.006); catalogued as COSV100852101; called by muse, mutect2
- PMS2 | c.1086G>A p.M362I | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.522); catalogued as COSV56220056; called by muse, mutect2, varscan2
- PNPT1 | c.1386T>G p.I462M | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.877); catalogued as COSV53175958; called by muse, mutect2, varscan2
- PPP1R12B | c.2300C>A p.T767K | Missense Mutation (SNP) | VAF 33/161 reads (20%) | SIFT tolerated (0.69); PolyPhen benign (0.007); catalogued as COSV51782310; called by muse, mutect2, varscan2
- PXDN | c.3482G>A p.R1161Q | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1396580675, COSV53228065; called by muse, mutect2, varscan2
- PZP | c.2207C>T p.T736M | Missense Mutation (SNP) | VAF 58/415 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as rs200058002; called by muse, mutect2, varscan2
- RAB11FIP4 | c.746C>T p.S249L | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as COSV57926853; called by muse, mutect2, varscan2
- RASGRF2 | c.617T>C p.I206T | Missense Mutation (SNP) | VAF 54/95 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.164); catalogued as COSV54123965; called by muse, mutect2, varscan2
- REEP2 | c.295A>G p.K99E | Missense Mutation (SNP) | VAF 39/74 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV54734586; called by muse, mutect2, varscan2
- RPL19 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.743); catalogued as COSV56634938; called by muse, mutect2, varscan2
- RSPH6A | c.2140G>A p.E714K | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.037); catalogued as COSV54287959; called by muse, mutect2, varscan2
- SCIMP | c.248T>C p.L83P | Missense Mutation (SNP) | VAF 94/173 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68310777; called by muse, mutect2, varscan2
- SEMA3G | c.2324C>T p.T775M | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.711); catalogued as rs759858543, COSV51594128; called by muse, mutect2, varscan2
- SLC13A3 | c.145G>T p.A49S | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51712317; called by muse, mutect2, varscan2
- SLC25A47 | c.259G>A p.G87S | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.029); catalogued as rs776000779, COSV64161564, COSV64161947; called by muse, mutect2, varscan2
- SLC4A9 | c.898C>A p.R300S (on ENST00000507527 / NM_001258428.2; = p.R276S on NM_031467.3) | Missense Mutation (SNP) | VAF 104/172 reads (60%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); catalogued as COSV50183759, COSV50184127; called by muse, mutect2, varscan2
- SOX9 | c.1432_1433dup p.I480Pfs*44 | Frame Shift Ins (INS) | VAF 32/122 reads (26%) | catalogued as COSV55430353; called by mutect2, pindel, varscan2
- TNS3 | c.3140C>T p.A1047V | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs764207972, COSV60787618; called by muse, mutect2
- TTN | c.78343A>T p.T26115S (on ENST00000591111; = p.T18691S on NM_003319.4) | Missense Mutation (SNP) | VAF 22/100 reads (22%) | PolyPhen benign (0.005); catalogued as COSV59914457; called by muse, mutect2, varscan2
- TTN | c.70973A>G p.K23658R (on ENST00000591111; = p.K16234R on NM_003319.4) | Missense Mutation (SNP) | VAF 12/86 reads (14%) | PolyPhen benign (0.003); catalogued as COSV59914482; called by muse, mutect2, varscan2
- WSCD2 | c.1199C>T p.T400M | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV54577557; called by muse, mutect2, varscan2
- ZFHX4 | c.8792G>A p.R2931H | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1251544718, COSV50580768; called by muse, mutect2
- ZNF492 | c.1525A>G p.S509G | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.041); catalogued as COSV71761728; called by muse, mutect2, varscan2
- ZNF595 | c.50A>C p.E17A | Missense Mutation (SNP) | VAF 26/572 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV100227499; called by muse, mutect2
- ZNF831 | c.1501G>A p.V501I | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.44); catalogued as rs546116387, COSV64037975; called by muse, mutect2, varscan2
- ZNF91 | c.934C>T p.H312Y | Missense Mutation (SNP) | VAF 70/416 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); catalogued as rs1196648229, COSV56081227; called by muse, mutect2, varscan2
- MAPKBP1 | c.1186del p.E396Rfs*6 (on ENST00000456763 / NM_001128608.2; = p.E390Rfs*6 on NM_014994.3) | Frame Shift Del (DEL) | VAF 61/144 reads (42%) | called by mutect2, pindel, varscan2
- RNASE1 | c.63_65del p.W22del | In Frame Del (DEL) | VAF 7/27 reads (26%) | called by mutect2, pindel
- WDR19 | c.1727_1728insCGA p.D579dup | In Frame Ins (INS) | VAF 24/84 reads (29%) | called by mutect2, varscan2
- ACVR1C | c.393G>A p.L131= | Silent (SNP) | VAF 5/144 reads (3%) | catalogued as COSV99694426; called by muse, mutect2
- ATP7A | c.2736C>G p.T912= | Silent (SNP) | VAF 24/192 reads (13%) | catalogued as COSV100430408; called by muse, mutect2, varscan2
- CHD4 | c.4032C>T p.D1344= (on ENST00000357008 / NM_001363606.2; = p.D1357= on NM_001273.5) | Silent (SNP) | VAF 53/160 reads (33%) | catalogued as rs1226084931, COSV58895963; called by muse, mutect2, varscan2
- CRISPLD1 | c.1377T>G p.G459= | Silent (SNP) | VAF 13/89 reads (15%) | catalogued as COSV51544976; called by muse, mutect2, varscan2
- GGTLC2 | c.354C>T p.D118= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as rs149680064, COSV67853898; called by muse, mutect2, varscan2
- GMIP | c.1920C>T p.Y640= | Silent (SNP) | VAF 31/75 reads (41%) | catalogued as rs367883715; called by muse, mutect2, varscan2
- HSPA9 | c.324G>A p.Q108= | Silent (SNP) | VAF 17/35 reads (49%) | catalogued as rs754498058, COSV51863493; called by muse, mutect2, varscan2
- IGKV1-6 | c.51C>T p.L17= | Silent (SNP) | VAF 95/266 reads (36%) | called by muse, varscan2
- ILDR1 | c.165C>T p.D55= | Silent (SNP) | VAF 21/63 reads (33%) | catalogued as rs748370597, COSV56548309; called by muse, mutect2, varscan2
- KCNB1 | c.762G>A p.K254= | Silent (SNP) | VAF 14/194 reads (7%) | catalogued as rs1166730645, COSV65566450; called by muse, mutect2
- OR4N2 | c.687T>C p.S229= | Silent (SNP) | VAF 77/304 reads (25%) | catalogued as COSV60050227, COSV60050379; called by muse, mutect2, varscan2
- PRDX6 | c.282C>T p.P94= | Silent (SNP) | VAF 22/100 reads (22%) | catalogued as rs779663146, COSV61165182; called by muse, mutect2, varscan2
- RIOX1 | c.1611C>T p.N537= | Silent (SNP) | VAF 19/70 reads (27%) | catalogued as COSV100407927; called by muse, mutect2, varscan2
- SERPINC1 | c.990A>G p.E330= | Silent (SNP) | VAF 20/139 reads (14%) | catalogued as COSV62928946; called by muse, mutect2, varscan2
- SRD5A2 | c.243G>A p.T81= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as COSV51870659; called by muse, mutect2
- TRAF3IP1 | c.807C>T p.R269= | Silent (SNP) | VAF 35/115 reads (30%) | catalogued as rs745750205, COSV64852163; called by muse, mutect2, varscan2
- TRIM10 | c.417G>A p.A139= | Silent (SNP) | VAF 26/94 reads (28%) | catalogued as rs373243528; called by muse, mutect2, varscan2
- ZNF516 | c.576C>T p.H192= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as rs1402378467, COSV71586738; called by muse, mutect2, varscan2
- FAM153CP | chr5:178055699 C>T | 3'Flank (SNP) | VAF 44/86 reads (51%) | catalogued as rs1043422120; called by muse, mutect2
- PYY3 | n.171C>T | RNA (SNP) | VAF 12/14 reads (86%) | catalogued as rs1037496361; called by muse, mutect2, varscan2
